CCDI case PBCIBC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/60ae999d-5620-4d7c-97b3-c0cb40fc5265

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 14.8 years (5,393 days).

Biospecimens (1 sample)
- Sample 0DSL0A: Tissue type: Tumor; Specimen type: Solid Tissue.
